Gene-level copy-number profile of tumor specimen TCGA-05-4396-01A from TCGA case TCGA-05-4396, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 76.9 years (28,094 days).
Specimen TCGA-05-4396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.2f28c6ef-1ad3-4089-8456-fca7a3fb5a59.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4396-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8612a2e0-9830-4afa-ae65-bbaca27d538a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 17,895; copy number 2: 40,549; copy number 3: 617; copy number 4: 226; copy number 5: 443; copy number 7: 33; copy number 9: 17; copy number 10: 2; copy number 15: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4396-01A-21D-1854-01): tumor purity 0.82, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:134,205,614–134,523,096, 16 genes (within-gene range 0–1): AC104109.4, MIR3661, AC104109.2, AC104109.1, CDKL3, UBE2B, AC109454.4, AC109454.2, CDKN2AIPNL, AC109454.1, AC109454.3, AC005355.1, RNU6-456P, LINC01843, RN7SL541P, AC005355.2.
- chr21:19,593,841–20,803,816, 13 genes: RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 503 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,933,643–59,240,555, 1 gene, copy number 5 (within-gene range 1–5): LINC01358.
- chr1:59,054,397–62,451,804, 38 genes, copy number 5–9: AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.3, AC099791.4, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2, PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P, USP1.
- chr1:90,388,193–92,184,725, 28 genes, copy number 5 (within-gene range 2–5): AL627316.1, LINC02787, SNORD3G, BARHL2, AC092805.1, LINC02609, LINC02788, LINC01763, AC091614.1, PHKA1P1, ZNF644, RPL5P6, HFM1, Y_RNA, FEN1P1, CDC7, WDR82P2, AL714022.1, HSP90B3P, TGFBR3, RN7SL653P, BRDT, EPHX4, LPCAT2BP, SETSIP, BTBD8, GAPDHP46, PRKAR1AP1.
- chr1:93,079,235–106,124,564, 180 genes, copy number 5–10 (broad region; genes not listed).
- chr1:114,673,090–121,580,524, 159 genes, copy number 5 (broad region; genes not listed).
- chr5:23,262,159–25,350,073, 33 genes, copy number 5: AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2.
- chr16:30,658,431–30,903,547, 23 genes, copy number 5: FBRS, RNU6-416P, AC093249.6, SRCAP, RNU6-1043P, AC106886.5, SNORA30, TMEM265, AC106886.2, PHKG2, CCDC189, RNF40, AC106886.4, ZNF629, Metazoa_SRP, AC106886.1, AC106886.3, BCL7C, MIR762HG, MIR4519, AC135048.2, MIR762, CTF1.
- chr18:14,450,216–15,330,282, 33 genes, copy number 7: LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr18:24,725,762–25,352,190, 8 genes, copy number 15 (within-gene range 3–15): AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1.

Autosomal genes at a single copy (total copy number 1): 15,508. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
